Somatic mutation profile of tumor specimen TCGA-D3-A3MV-06A (aliquot TCGA-D3-A3MV-06A-11D-A21A-08) from TCGA case TCGA-D3-A3MV, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 40.3 years (14,725 days).
Specimen TCGA-D3-A3MV-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e74225bc-0d11-43c2-9ac2-c701943ba4fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3MV-10A (Blood Derived Normal), aliquot TCGA-D3-A3MV-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6393930d-ce00-41a3-92e2-8fa0816a1eb2

The open-access MAF lists 635 somatic variants for this specimen: 391 protein-altering or splice-affecting, 232 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 346, Silent 232, Nonsense Mutation 32, Splice Site 7, Intron 5, RNA 4, Frame Shift Del 3, 3'UTR 2, 5'UTR 1, In Frame Del 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL2L12 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.796); catalogued as rs1057519880, COSV55862483; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 28/37 reads (76%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs779156384, COSV54070747; called by muse, mutect2, varscan2
- HLCS | c.1088T>A p.V363D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769499327, CM960832, COSV100358327; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.157T>A p.F53I | Missense Mutation (SNP) | VAF 43/146 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1057519728, COSV61068605, COSV61070825, COSV61071840; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 113/162 reads (70%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51709885; called by muse, mutect2, varscan2
- ACACB | c.6105A>T p.E2035D | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV58134910; called by muse, mutect2, varscan2
- ACTN4 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV53146077, COSV99400818; called by muse, mutect2, varscan2
- ACTRT1 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1211355697, COSV100947606, COSV64418902; called by muse, mutect2, varscan2
- ACTRT1 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.194); catalogued as COSV64419392; called by muse, mutect2, varscan2
- ADAM2 | c.2145dup p.W716Mfs*4 | Frame Shift Ins (INS) | VAF 32/92 reads (35%) | catalogued as rs764499662; called by mutect2, pindel, varscan2
- ADGRG2 | c.1232C>T p.S411F (on ENST00000379869 / NM_001079858.3; = p.S408F on NM_005756.4) | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV61339170; called by muse, mutect2, varscan2
- ADGRL4 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV66061701; called by muse, mutect2, varscan2
- AGK | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV62594547; called by muse, mutect2, varscan2
- ALPK2 | c.4330G>A p.E1444K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs370248466, COSV64490192; called by muse, mutect2
- AMHR2 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs766690921, COSV57685768; called by muse, mutect2, varscan2
- ANAPC10 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT tolerated (0.11); PolyPhen benign (0.258); catalogued as COSV58739530; called by muse, mutect2, varscan2
- ANK3 | c.11033C>T p.P3678L | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.036); catalogued as COSV55058278; called by muse, mutect2, varscan2
- ANK3 | c.6391G>A p.E2131K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV55053323, COSV55058299; called by muse, mutect2, varscan2
- ANKS1B | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.953); catalogued as rs778044550, COSV61351807; called by muse, mutect2, varscan2
- APCDD1 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV62372505; called by muse, mutect2, varscan2
- AQR | c.2939C>T p.P980L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50034810; called by muse, mutect2, varscan2
- ARHGAP44 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52394219; called by muse, varscan2
- ARHGAP44 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs974511189, COSV52394226; called by muse, mutect2, varscan2
- ARHGEF5 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV50210434; called by muse, mutect2, varscan2
- ARL13A | c.722A>G p.K241R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65880153; called by muse, mutect2, varscan2
- ARMC5 | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV51656496; called by muse, mutect2, varscan2
- ARRDC5 | c.730C>T p.R244W (on ENST00000381781; = p.R230W on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as rs548886303, COSV67787986; called by muse, mutect2, varscan2
- ARSF | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs985603182, COSV63839651; called by muse, mutect2, varscan2
- ARSK | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 63/84 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780938904, COSV66169681; called by muse, mutect2, varscan2
- ASPHD2 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.022); catalogued as rs764816494, COSV53219033; called by muse, mutect2, varscan2
- ATP2B2 | c.2281G>A p.E761K (on ENST00000352432; = p.E727K on NM_001683.5) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.138); catalogued as COSV100660053; called by muse, mutect2, varscan2
- ATP6V0D2 | c.955A>C p.K319Q | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53415030; called by muse, mutect2, varscan2
- ATP8B4 | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.045); catalogued as COSV52715754; called by muse, mutect2, varscan2
- ATRX | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs1557142507, COSV64876751; called by muse, mutect2, varscan2
- AXDND1 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 148/197 reads (75%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV100858228, COSV62642768; called by muse, mutect2, varscan2
- BARHL2 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 59/80 reads (74%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as rs572958991, COSV64981275; called by muse, mutect2, varscan2
- BAZ2A | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV51636881; called by muse, mutect2, varscan2
- BEND2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV66215859; called by muse, mutect2, varscan2
- BEND4 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.978); catalogued as rs754744473, COSV72469053; called by muse, mutect2, varscan2
- BMP6 | c.1371C>A p.N457K | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51665596; called by muse, mutect2, varscan2
- BRPF3 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60207447, COSV60210629; called by muse, mutect2, varscan2
- BSN | c.5977G>A p.G1993S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV56518032; called by muse, mutect2, varscan2
- C10orf71 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as COSV60505226, COSV60507803; called by muse, mutect2, varscan2
- C5 | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0.388); catalogued as COSV56327339; called by muse, mutect2, varscan2
- C8A | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV63483118; called by muse, mutect2, varscan2
- CACNA1G | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV61727582; called by muse, mutect2, varscan2
- CADM2 | c.728C>T p.P243L (on ENST00000407528 / NM_001167674.2; = p.P245L on NM_153184.4) | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV67375248; called by muse, mutect2, varscan2
- CADPS | c.3677G>A p.G1226E | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99339167; called by muse, mutect2, varscan2
- CADPS | c.3676G>A p.G1226R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs566247034, COSV99339169; called by muse, mutect2
- CANT1 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 66/216 reads (31%) | catalogued as rs372332465; called by muse, mutect2, varscan2
- CAPZA3 | c.521G>A p.W174* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as rs868817065, COSV56852732; called by muse, mutect2, varscan2
- CARMIL1 | c.3866C>T p.P1289L | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); catalogued as COSV61517585; called by muse, mutect2, varscan2
- CCBE1 | c.793G>C p.G265R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67949959, COSV67950269; called by muse, mutect2, varscan2
- CCDC144A | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as COSV60698377; called by muse, mutect2, varscan2
- CCDC60 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.167); catalogued as rs1297066120, COSV59540844; called by muse, mutect2, varscan2
- CCRL2 | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.192); catalogued as COSV62193506; called by muse, mutect2, varscan2
- CD163 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 15/342 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as COSV63132309; called by muse, mutect2
- CD177 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.86); catalogued as rs940536653, COSV65121336; called by muse, mutect2, varscan2
- CD177 | c.1253G>A p.W418* | Nonsense Mutation (SNP) | VAF 9/15 reads (60%) | catalogued as rs772586043, COSV65121341; called by muse, mutect2, varscan2
- CD207 | c.614A>T p.N205I | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV101338572, COSV69651932; called by muse, mutect2, varscan2
- CD63 | c.256-1G>A p.X86_splice | Splice Site (SNP) | VAF 76/139 reads (55%) | catalogued as COSV57676424; called by muse, mutect2, varscan2
- CD96 | c.947G>A p.G316E (on ENST00000283285 / NM_198196.3; = p.G300E on NM_005816.5) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.028); catalogued as COSV51916437; called by muse, mutect2, varscan2
- CDC25B | c.329G>A p.G110D (on ENST00000245960 / NM_021873.3; = p.G96D on NM_004358.4) | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55656650; called by muse, mutect2, varscan2
- CDC27 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV50375857; called by muse, mutect2, varscan2
- CDH4 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV64655022; called by muse, mutect2, varscan2
- CDH8 | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV54866417, COSV54867931; called by muse, mutect2, varscan2
- CDRT1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55411763; called by muse, mutect2, varscan2
- CENPE | c.7975C>T p.R2659C | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs774765853, COSV54381302; called by muse, mutect2, varscan2
- CEP290 | c.6727G>A p.E2243K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100469042; called by mutect2, varscan2
- CHL1 | c.2638C>T p.P880S (on ENST00000397491 / NM_001253387.1; = p.P896S on NM_006614.4) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.517); catalogued as rs775757574, COSV56593671; called by muse, mutect2, varscan2
- CHRNA3 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.861); catalogued as COSV58775320; called by muse, mutect2, varscan2
- CLCN6 | c.608T>C p.M203T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV56740184; called by muse, mutect2, varscan2
- CLDN6 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 54/72 reads (75%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.474); catalogued as rs776406970, COSV58509497; called by muse, mutect2, varscan2
- CLPB | c.2098C>G p.P700A | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53629923; called by muse, mutect2, varscan2
- CNTN2 | c.2618C>T p.A873V | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV59350059; called by muse, mutect2, varscan2
- CNTN6 | c.2291G>A p.R764K | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.952); catalogued as rs756067438, COSV100609741, COSV63166015, COSV63172489; called by muse, mutect2, varscan2
- CNTN6 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs531023205, COSV63172494; called by muse, mutect2, varscan2
- COL22A1 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV57337325; called by muse, mutect2, varscan2
- COL3A1 | c.4048C>T p.L1350F | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as COSV58584524; called by muse, mutect2, varscan2
- COL6A3 | c.5965G>A p.E1989K | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV55089682; called by muse, mutect2, varscan2
- CORIN | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56691630; called by muse, mutect2, varscan2
- CORIN | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 60/85 reads (71%) | SIFT tolerated (0.48); PolyPhen benign (0.205); catalogued as rs866164544, COSV56688788; called by muse, mutect2, varscan2
- CPAMD8 | c.2386G>A p.E796K (on ENST00000651564; = p.E749K on NM_015692.5) | Missense Mutation (SNP) | VAF 104/183 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs531351431, COSV52230787; called by muse, mutect2, varscan2
- CRACDL | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168021661, COSV67408148; called by muse, mutect2, varscan2
- CSF2RB | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs763415308, COSV53255870; called by muse, mutect2, varscan2
- CTCFL | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs781496791, COSV54774465; called by muse, mutect2, varscan2
- CUL5 | c.411G>A p.K137= | Splice Region (SNP) | VAF 32/41 reads (78%) | catalogued as COSV67608906; called by muse, mutect2, varscan2
- CUX2 | c.4157C>T p.S1386F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV55632389; called by muse, mutect2, varscan2
- CYB5R1 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV65916985; called by muse, mutect2, varscan2
- CYP3A4 | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV60502034; called by muse, mutect2, varscan2
- CYP4X1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64150723; called by muse, mutect2, varscan2
- CYP4Z1 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV61964999; called by muse, mutect2, varscan2
- CYTIP | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV51633799; called by muse, mutect2, varscan2
- DCC | c.3835C>T p.L1279F | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.932); catalogued as COSV71432198; called by muse, mutect2, varscan2
- DCLK3 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs765395912, COSV69363184, COSV69364256; called by muse, mutect2, varscan2
- DENND3 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52801418; called by muse, mutect2, varscan2
- DENND4B | c.3215C>A p.P1072H | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV63409188; called by muse, mutect2, varscan2
- DENND6B | c.229T>C p.C77R | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV69806946; called by muse, mutect2, varscan2
- DHX57 | c.2638C>T p.R880* | Nonsense Mutation (SNP) | VAF 26/50 reads (52%) | catalogued as rs965943997, COSV99769657; called by muse, mutect2, varscan2
- DICER1 | c.2483C>T p.S828F | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58620122; called by muse, mutect2, varscan2
- DLC1 | c.1859C>T p.S620F (on ENST00000276297 / NM_001348081.2; = p.S183F on NM_006094.5) | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV52291251; called by muse, mutect2, varscan2
- DLGAP2 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1184349817, COSV70098356; called by muse, mutect2, varscan2
- DLGAP2 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as COSV70098363; called by muse, mutect2, varscan2
- DLL1 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV100816120, COSV100816195; called by muse, mutect2, varscan2
- DMC1 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV53259216; called by muse, mutect2, varscan2
- DNAH5 | c.4615G>A p.V1539M | Missense Mutation (SNP) | VAF 65/102 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.378); catalogued as COSV54225239; called by muse, mutect2, varscan2
- DNAH8 | c.4225G>A p.D1409N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59445926; called by muse, mutect2, varscan2
- DNAH8 | c.13254G>T p.M4418I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV59445954; called by muse, mutect2, varscan2
- DNM3 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1183572066, COSV62457525; called by muse, mutect2, varscan2
- DPPA2 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV72117929; called by muse, mutect2, varscan2
- DRD1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67104613; called by muse, mutect2, varscan2
- DSC1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1419296981, COSV57145756; called by muse, mutect2, varscan2
- DSC2 | c.1912C>T p.Q638* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV51864696; called by muse, mutect2, varscan2
- DSCAM | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.977); catalogued as rs267606132, COSV68024849; called by muse, mutect2
- DSCAM | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV68026863; called by muse, mutect2, varscan2
- DSG1 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV57135382; called by muse, mutect2, varscan2
- DSG4 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293646965, COSV57391776; called by muse, mutect2, varscan2
- DUOX2 | c.1950G>A p.M650I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV66532171; called by muse, mutect2, varscan2
- DZIP1 | c.2182G>A p.E728K (on ENST00000347108; = p.E709K on NM_014934.5) | Missense Mutation (SNP) | VAF 116/155 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.277); catalogued as rs1444367378, COSV61264299; called by muse, mutect2, varscan2
- ECT2L | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV62884517; called by muse, mutect2
- EGR4 | c.1583T>C p.L528P (on ENST00000545030; = p.L425P on NM_001965.4) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71532038; called by muse, mutect2, varscan2
- ELAVL3 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV63645620; called by muse, mutect2, varscan2
- ELOA3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV55294493; called by muse, mutect2, varscan2
- EPB41L1 | c.2258C>T p.S753L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs779265640, COSV52437923; called by muse, mutect2, varscan2
- EPHA1 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51971306; called by muse, mutect2, varscan2
- EPHA7 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as COSV65178458; called by muse, mutect2, varscan2
- EPHA7 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65169361; called by muse, mutect2, varscan2
- ERICH6 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55800463; called by muse, mutect2, varscan2
- ESPL1 | c.5086C>T p.Q1696* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV57759495; called by muse, mutect2, varscan2
- FAM135B | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV52725565, COSV52726252; called by muse, varscan2
- FAM135B | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 36/134 reads (27%) | catalogued as COSV52725585; called by muse, varscan2
- FARSB | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV56049685; called by muse, mutect2, varscan2
- FAT3 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs867563989, COSV53111512; called by muse, mutect2, varscan2
- FBP2 | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.953); catalogued as rs755644556, COSV64694407; called by muse, mutect2, varscan2
- FBXL13 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs137980271; called by muse, mutect2, varscan2
- FCN2 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 65/96 reads (68%) | catalogued as rs780002054, COSV52477017; called by muse, mutect2, varscan2
- FER1L6 | c.3400C>T p.H1134Y | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV67549957; called by muse, mutect2, varscan2
- FGF14 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65944004; called by muse, mutect2, varscan2
- FIGNL2 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73729234; called by muse, mutect2, varscan2
- FLNC | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 167/404 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV57955972; called by muse, mutect2, varscan2
- FMNL2 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV56495217; called by muse, mutect2, varscan2
- FMNL2 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV56495232; called by muse, mutect2, varscan2
- FNDC1 | c.5301G>A p.W1767* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV51932123; called by muse, mutect2, varscan2
- FOXD4 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | PolyPhen benign (0); catalogued as rs752247035, COSV58700238; called by muse, mutect2, varscan2
- FOXN1 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV56881841; called by muse, mutect2, varscan2
- FUT2 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.243); catalogued as COSV67179323; called by muse, mutect2, varscan2
- GCA | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV52025528; called by muse, mutect2, varscan2
- GFM1 | c.1108T>C p.Y370H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51832748; called by muse, mutect2, varscan2
- GGA1 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV57330019; called by muse, mutect2, varscan2
- GIMAP6 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV61033425, COSV61034772; called by muse, mutect2, varscan2
- GIMAP8 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs750008473, COSV56231017; called by muse, mutect2, varscan2
- GPATCH2 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 65/94 reads (69%) | catalogued as rs780186754, COSV65129431; called by muse, mutect2, varscan2
- GPR139 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 117/172 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs756813774, COSV58502931; called by muse, mutect2, varscan2
- GRHL2 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV52548592; called by muse, mutect2, varscan2
- GRIN2A | c.1451A>T p.K484M | Missense Mutation (SNP) | VAF 79/123 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58033301; called by muse, mutect2, varscan2
- H1-5 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as rs773069523, COSV58900081; called by muse, mutect2, varscan2
- HACE1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as COSV53502493; called by muse, mutect2, varscan2
- HDHD2 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs141476363; called by muse, mutect2, varscan2
- HECW1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.449); catalogued as rs369348156, COSV67829726; called by muse, mutect2, varscan2
- HECW2 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs748951495, COSV53659886, COSV99648664; called by muse, mutect2, varscan2
- HERC2 | c.4756C>T p.P1586S | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99874783; called by muse, mutect2, varscan2
- HERC6 | c.1180A>T p.K394* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV52030136; called by muse, mutect2, varscan2
- HTRA4 | c.9A>C p.R3S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV56759399; called by muse, mutect2, varscan2
- HYDIN | c.6301G>A p.E2101K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV59256723; called by muse, mutect2, varscan2
- HYKK | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV66460138; called by muse, mutect2, varscan2
- IFFO1 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.133); catalogued as COSV59110628; called by muse, mutect2, varscan2
- IFT57 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1391492471, COSV52709664; called by muse, mutect2, varscan2
- IGHD | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV101162939; called by muse, mutect2, varscan2
- IGLV2-23 | c.317A>C p.D106A | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.391); catalogued as rs780233568; called by muse, mutect2, varscan2
- IGSF1 | c.3185G>A p.G1062D | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV63837543; called by muse, mutect2, varscan2
- IL1RN | c.185G>A p.G62E (on ENST00000409930 / NM_173842.3; = p.G44E on NM_000577.5) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs1203011392, COSV52080700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL6ST | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61141295; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs758021879, COSV59349077; called by muse, mutect2, varscan2
- ITGA6 | c.1735C>T p.R579* (on ENST00000442250; = p.R540* on NM_000210.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as rs751599520, CM981078, COSV51225109; called by muse, mutect2, varscan2
- ITIH2 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs185942404; called by muse, mutect2, varscan2
- JAKMIP2 | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 50/71 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as COSV54604792; called by muse, mutect2, varscan2
- KCNB2 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV73049213; called by muse, mutect2, varscan2
- KCNC3 | c.2170+1G>A p.X724_splice | Splice Site (SNP) | VAF 10/18 reads (56%) | catalogued as COSV65387368; called by muse, mutect2, varscan2
- KCNF1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV54463499; called by muse, mutect2, varscan2
- KCNH8 | c.2891C>T p.S964F | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.203); catalogued as COSV60464108; called by muse, mutect2, varscan2
- KCNK15 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV100865831; called by muse, mutect2
- KCNK7 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs570596099, COSV58419647; called by muse, mutect2, varscan2
- KCNV1 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV52086189; called by muse, mutect2, varscan2
- KDR | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs776989013, COSV55765263; called by muse, mutect2, varscan2
- KERA | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV57130420, COSV57130677; called by muse, mutect2, varscan2
- KHDC3L | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 51/113 reads (45%) | catalogued as COSV64869049; called by muse, mutect2, varscan2
- KIF15 | c.1510-1G>A p.X504_splice | Splice Site (SNP) | VAF 54/126 reads (43%) | catalogued as COSV58160896; called by muse, mutect2, varscan2
- KIF23 | c.1810T>C p.F604L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52979847; called by muse, mutect2, varscan2
- KLHDC7A | c.2278C>A p.L760I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV68769783; called by muse, mutect2, varscan2
- KLHL24 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.02); catalogued as COSV54426238; called by muse, mutect2, varscan2
- KRT4 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757780016, COSV53407294; called by muse, mutect2, varscan2
- LAMA1 | c.7040C>T p.S2347L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67537162; called by muse, mutect2, varscan2
- LARP4B | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV60221507; called by muse, mutect2, varscan2
- LRP1B | c.13450G>A p.G4484R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67221305; called by muse, mutect2
- LRP1B | c.12778G>A p.G4260R | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV67221309; called by muse, mutect2, varscan2
- LRRTM4 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV69140170; called by muse, mutect2, varscan2
- LTBP4 | c.1334A>T p.Q445L (on ENST00000308370 / NM_001042544.1; = p.Q408L on NM_003573.2) | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV52581706; called by muse, mutect2, varscan2
- LYRM4 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 24/137 reads (18%) | catalogued as rs370913062; called by muse, mutect2, varscan2
- MAGEC1 | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV53572902, COSV99595402; called by muse, mutect2, varscan2
- MARCHF7 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 100/414 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1367835134, COSV52028880; called by muse, mutect2, varscan2
- MEP1A | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57920005; called by muse, mutect2, varscan2
- MINK1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61790143; called by muse, mutect2, varscan2
- MMP12 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58259859; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3030-2A>T p.X1010_splice | Splice Site (SNP) | VAF 18/57 reads (32%) | catalogued as COSV56619862; called by muse, mutect2, varscan2
- MPP1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs781808389, COSV65728010, COSV65728208; called by muse, mutect2
- MPP2 | c.808T>G p.C270G (on ENST00000461854 / NM_001278372.2; = p.C246G on NM_005374.5) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52235910; called by muse, mutect2, varscan2
- MROH2B | c.3792G>A p.M1264I | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV68184219; called by muse, mutect2, varscan2
- MRPS23 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV100551452; called by muse, mutect2, varscan2
- MS4A14 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55729875; called by muse, mutect2, varscan2
- MUC16 | c.30380C>T p.S10127F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.937); catalogued as COSV67466624; called by muse, mutect2, varscan2
- MUC16 | c.6578C>T p.S2193F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67462513; called by muse, mutect2
- MUC16 | c.5128G>A p.E1710K | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); catalogued as COSV67446409; called by muse, mutect2, varscan2
- MUC5B | c.15052G>A p.E5018K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV71592081; called by muse, mutect2, varscan2
- MUTYH | c.1201T>C p.F401L | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV58344146; called by muse, mutect2, varscan2
- MYBBP1A | c.3947C>T p.A1316V | Missense Mutation (SNP) | VAF 79/148 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV54597727; called by muse, mutect2, varscan2
- MYH2 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 119/241 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55433645; called by muse, mutect2, varscan2
- MYH2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs756281353, COSV55438538, COSV99820030; called by muse, mutect2, varscan2
- MYO1F | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs750553132, COSV57795167; called by muse, mutect2, varscan2
- MYO1H | c.2180G>A p.R727K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.044); catalogued as COSV60445811; called by muse, mutect2, varscan2
- NECAP1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 156/350 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs1185645281, COSV60249367; called by muse, mutect2, varscan2
- NEFM | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as COSV55332210; called by muse, mutect2, varscan2
- NES | c.4130C>T p.P1377L | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100957903, COSV63960338; called by muse, mutect2, varscan2
- NES | c.4129C>T p.P1377S | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769121033, COSV100957904; called by muse, mutect2, varscan2
- NEXMIF | c.3787C>T p.Q1263* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV50031733; called by muse, mutect2, varscan2
- NLRP7 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); catalogued as COSV60174608; called by muse, mutect2, varscan2
- NOP58 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51896665; called by muse, mutect2, varscan2
- NOS3 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs1563219948, COSV52489857; called by muse, mutect2, varscan2
- OAS1 | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs903308626, COSV99177193; called by muse, mutect2, varscan2
- OPN1SW | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV50821759; called by muse, mutect2, varscan2
- OR10J1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 81/110 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71128868; called by muse, mutect2, varscan2
- OR11H12 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 72/107 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs369314954; called by muse, mutect2, varscan2
- OR11L1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs202119268, COSV63314778; called by muse, mutect2, varscan2
- OR1E1 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV59458974; called by muse, mutect2, varscan2
- OR2AG2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100643155, COSV58455183; called by muse, mutect2, varscan2
- OR51D1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as rs375185822; called by muse, mutect2, varscan2
- OR5AC2 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562786394, COSV100684561, COSV62279251; called by muse, mutect2, varscan2
- OR5AC2 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV62279253, COSV62279601; called by muse, mutect2, varscan2
- OR5T2 | c.344T>G p.V115G | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV57589232; called by muse, mutect2, varscan2
- OR6C3 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.32); catalogued as COSV65571162; called by muse, mutect2, varscan2
- OR6C6 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.12); catalogued as COSV64455766; called by muse, mutect2, varscan2
- OR6C74 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.056); catalogued as rs777439706, COSV59605795; called by muse, mutect2, varscan2
- OR7G1 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as rs1354696982, COSV53317721; called by muse, mutect2, varscan2
- OR9A4 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV71885456, COSV71885463; called by muse, mutect2, varscan2
- OR9A4 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV71885464; called by muse, mutect2, varscan2
- OXLD1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV61303331; called by muse, mutect2, varscan2
- PAK5 | c.1869+1G>A p.X623_splice | Splice Site (SNP) | VAF 103/205 reads (50%) | catalogued as COSV62026505; called by muse, mutect2, varscan2
- PAM | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV57213286; called by muse, mutect2, varscan2
- PAX7 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 63/87 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64750249; called by muse, mutect2, varscan2
- PCARE | c.3023G>A p.R1008K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs1409675064, COSV59055014; called by muse, mutect2, varscan2
- PCDHA7 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 58/75 reads (77%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV65342100, COSV65343224; called by muse, mutect2, varscan2
- PCDHB16 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1291792620, COSV53359199; called by muse, mutect2, varscan2
- PCDHB7 | c.1964C>T p.T655I | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV50768443; called by muse, varscan2
- PCDHB8 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 54/501 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50768444; called by muse, mutect2, varscan2
- PCDHGA3 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV53949643; called by muse, mutect2, varscan2
- PCDHGB7 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV53924989, COSV53949660; called by muse, mutect2, varscan2
- PDE1B | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as COSV54492839; called by muse, mutect2, varscan2
- PELI2 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV50711277; called by muse, mutect2, varscan2
- PHYH | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 114/189 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV53815845; called by muse, mutect2, varscan2
- PIK3C2G | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs1009436030, COSV56803581; called by muse, mutect2, varscan2
- PKHD1L1 | c.9361C>T p.P3121S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65743085; called by muse, mutect2, varscan2
- PLCB2 | c.3496C>T p.P1166S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as COSV53033610, COSV99541869; called by muse, mutect2, varscan2
- PLCD3 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs200400202; called by muse, mutect2, varscan2
- PLCZ1 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV56852718; called by muse, mutect2, varscan2
- PLEKHO1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 110/145 reads (76%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as rs141386276; called by muse, mutect2, varscan2
- PLXNA4 | c.902A>G p.E301G | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV58126607; called by muse, mutect2, varscan2
- POF1B | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.915); catalogued as COSV53134246; called by muse, mutect2, varscan2
- PON1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55931955; called by muse, mutect2, varscan2
- POU2F2 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV60762788; called by muse, mutect2, varscan2
- PPFIA4 | c.3327C>G p.D1109E (on ENST00000447715; = p.D1110E on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55315157, COSV55318570; called by muse, mutect2, varscan2
- PPP6C | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101001267, COSV65207059; called by muse, mutect2, varscan2
- PREX1 | c.4360C>T p.R1454C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762767897, COSV64256772; called by muse, mutect2, varscan2
- PREX2 | c.4262G>A p.R1421K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs901857351, COSV55770624; called by muse, mutect2, varscan2
- PSG3 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 181/319 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1413817902, COSV59504297; called by muse, mutect2, varscan2
- PTPRK | c.3263G>A p.R1088Q (on ENST00000368215 / NM_001291984.2; = p.R1089Q on NM_002844.4) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1302382517, COSV63893927; called by muse, mutect2, varscan2
- PTPRN | c.2794+1G>A p.X932_splice | Splice Site (SNP) | VAF 20/111 reads (18%) | catalogued as COSV55345735; called by muse, mutect2, varscan2
- PWWP3B | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs764749806, COSV61799799; called by muse, mutect2, varscan2
- PXDNL | c.2981G>A p.G994E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867225480, COSV62485869; called by muse, mutect2, varscan2
- QRICH1 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58707942; called by muse, mutect2, varscan2
- RALYL | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567857079, COSV72818303; called by muse, mutect2, varscan2
- RANBP2 | c.7354C>T p.H2452Y | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.503); catalogued as COSV99312487; called by muse, mutect2, varscan2
- RBM12B | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs763716003, COSV66968165; called by muse, mutect2, varscan2
- RBMXL2 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs187868291, COSV60980133; called by muse, mutect2, varscan2
- RFX6 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV60585060; called by muse, mutect2, varscan2
- RIMS1 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV53456511; called by muse, mutect2, varscan2
- RNF165 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as COSV53973737; called by muse, mutect2, varscan2
- RPS20 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV50536466; called by muse, mutect2, varscan2
- RRAD | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs755715208, COSV55336657; called by muse, mutect2, varscan2
- RRP9 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs760648950, COSV51754379; called by muse, mutect2, varscan2
- RTL9 | c.2628G>A p.M876I | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV101511792, COSV71825627; called by muse, mutect2, varscan2
- RYR3 | c.4753G>A p.D1585N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as rs781031032, COSV66789750; called by muse, mutect2, varscan2
- SAMD7 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV59418771; called by muse, mutect2, varscan2
- SATB1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58669537; called by muse, mutect2, varscan2
- SCN11A | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100181824; called by muse, mutect2, varscan2
- SELENOT | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as COSV71982270; called by muse, mutect2, varscan2
- SEMA4B | c.1385A>T p.D462V | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.915); catalogued as COSV100153341; called by muse, mutect2, varscan2
- SEMA4D | c.2519C>T p.S840F | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV59394972; called by muse, mutect2, varscan2
- SGCZ | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV66014614; called by muse, varscan2
- SH3TC1 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as COSV55284278; called by muse, mutect2, varscan2
- SHC3 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65438415, COSV65439153; called by muse, mutect2, varscan2
- SLC12A6 | c.448C>T p.L150F (on ENST00000354181 / NM_001365088.1; = p.L99F on NM_005135.2) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV51626146; called by muse, mutect2, varscan2
- SLC26A3 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV60640348; called by muse, mutect2, varscan2
- SLCO1A2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); catalogued as rs866943138, COSV56601007, COSV56602235; called by muse, mutect2, varscan2
- SLCO1B3 | c.1544G>A p.R515K | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV53934447, COSV53937619; called by muse, mutect2, varscan2
- SMARCA2 | c.4256C>T p.S1419L | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV56646598; called by muse, mutect2, varscan2
- SNX17 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV52007844; called by muse, mutect2, varscan2
- SPAG17 | c.2619G>A p.M873I | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV60459056; called by muse, mutect2, varscan2
- SPATA31E1 | c.1919C>T p.S640F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.607); catalogued as COSV57789448, COSV57791463; called by muse, mutect2, varscan2
- SPICE1 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1171730469, COSV55620613; called by muse, mutect2, varscan2
- SPTBN2 | c.5446C>T p.R1816W | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs757668466, COSV59452266; called by muse, mutect2, varscan2
- SPTBN4 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58949572; called by muse, mutect2, varscan2
- SRGAP3 | c.1985C>T p.T662I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64533357; called by muse, mutect2, varscan2
- ST8SIA3 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 49/118 reads (42%) | PolyPhen probably damaging (1); catalogued as rs145545626, COSV60653431, COSV60654584; called by muse, mutect2, varscan2
- STAP1 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV55327734; called by muse, mutect2, varscan2
- STXBP5L | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1049911337, COSV56514186; called by muse, mutect2, varscan2
- SULT2B1 | c.880G>A p.D294N (on ENST00000201586 / NM_177973.2; = p.D279N on NM_004605.2) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.236); catalogued as rs201648343, COSV52375104; called by muse, mutect2, varscan2
- SVEP1 | c.7858G>A p.D2620N | Missense Mutation (SNP) | VAF 101/139 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52839408; called by muse, mutect2, varscan2
- SVOPL | c.1444G>A p.E482K (on ENST00000419765; = p.E330K on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs770776844, COSV55988799; called by muse, mutect2, varscan2
- TANC2 | c.5794G>A p.G1932R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.726); catalogued as rs1377406981, COSV67334494; called by muse, mutect2, varscan2
- TBC1D23 | c.446T>A p.F149Y | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV61368010; called by muse, mutect2, varscan2
- TCF4 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV61896907; called by muse, mutect2, varscan2
- TCHHL1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 81/105 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV64285752; called by muse, mutect2, varscan2
- TFB1M | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.292); catalogued as COSV51640576; called by mutect2, varscan2
- TICRR | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV51541615; called by muse, mutect2, varscan2
- TJP1 | c.3988C>T p.Q1330* | Nonsense Mutation (SNP) | VAF 41/72 reads (57%) | catalogued as COSV62042054; called by muse, mutect2, varscan2
- TLR5 | c.2549C>T p.P850L | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs749314437, CM142635, COSV60559079, COSV60560762; called by muse, mutect2, varscan2
- TMEM132B | c.2558C>T p.P853L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as COSV54754081; called by muse, mutect2, varscan2
- TMEM200A | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1042646760, COSV51649569, COSV99759006; called by muse, mutect2, varscan2
- TMEM209 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV100390492; called by muse, mutect2, varscan2
- TMEM35A | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); catalogued as COSV54502852, COSV54503909; called by muse, mutect2, varscan2
- TMEM38B | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV65949968; called by muse, mutect2, varscan2
- TNFAIP3 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52798450; called by muse, mutect2, varscan2
- TNFRSF10D | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.041); catalogued as COSV57035779; called by muse, mutect2, varscan2
- TNFRSF21 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57281995; called by muse, mutect2, varscan2
- TNRC6C | c.3698C>T p.S1233L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1486137355, COSV56945324; called by muse, mutect2, varscan2
- TNS4 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs746526282, COSV54185056; called by mutect2, varscan2
- TNXB | c.8351C>T p.S2784L (on ENST00000647633; = p.S2537L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758988241, COSV64479086; called by muse, mutect2, varscan2
- TOP3A | c.2099G>A p.R700K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100329342, COSV58177455; called by muse, mutect2, varscan2
- TPTE | c.1273C>T p.P425S (on ENST00000618007 / NM_199261.4; = p.P407S on NM_199259.4) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as rs138794341; called by muse, mutect2, varscan2
- TRIOBP | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.996); catalogued as rs748631543, COSV60377601; called by muse, mutect2, varscan2
- TRMT2B | c.539-1G>A p.X180_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | catalogued as COSV58619603; called by muse, mutect2, varscan2
- TROAP | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371702007, COSV57744123; called by muse, varscan2
- TTN | c.64557G>A p.W21519* (on ENST00000591111; = p.W14095* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100591696, COSV60068224; called by muse, mutect2, varscan2
- TTN | c.54016G>A p.G18006R (on ENST00000591111; = p.G10582R on NM_003319.4) | Missense Mutation (SNP) | VAF 30/77 reads (39%) | PolyPhen probably damaging (1); catalogued as rs201430346; called by muse, mutect2, varscan2
- TTN | c.32062C>T p.P10688S (on ENST00000591111; = p.P9761S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/167 reads (51%) | PolyPhen benign (0.178); catalogued as rs758199108, COSV60068336; called by muse, mutect2, varscan2
- TTN | c.6278C>T p.S2093F (on ENST00000591111; = p.S2047F on NM_003319.4) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | PolyPhen benign (0.444); catalogued as COSV60068346; called by muse, mutect2, varscan2
- UGGT2 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV65025385; called by muse, mutect2, varscan2
- UHRF1 | c.2129C>T p.P710L (on ENST00000612630 / NM_001290050.1; = p.P723L on NM_013282.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs758518832, COSV53574654; called by muse, mutect2, varscan2
- UNC13A | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.645); catalogued as COSV53196021; called by muse, mutect2, varscan2
- USH1C | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV50016624; called by muse, mutect2, varscan2
- USH2A | c.6700G>A p.A2234T | Missense Mutation (SNP) | VAF 90/107 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV56370761; called by muse, mutect2, varscan2
- USP21 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.528); catalogued as COSV57088702; called by muse, mutect2, varscan2
- VEGFC | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 80/119 reads (67%) | catalogued as rs1452319332, COSV54598261; called by muse, mutect2, varscan2
- VSIG1 | c.436del p.S146Afs*40 | Frame Shift Del (DEL) | VAF 29/85 reads (34%) | catalogued as COSV54261417; called by mutect2, pindel, varscan2
- WDR75 | c.1888C>T p.Q630* | Nonsense Mutation (SNP) | VAF 58/184 reads (32%) | catalogued as COSV59105585; called by muse, mutect2, varscan2
- WFDC8 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.591); catalogued as COSV51489681; called by muse, mutect2, varscan2
- WLS | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs544767216, COSV52039619; called by muse, mutect2, varscan2
- WNK1 | c.4427C>T p.S1476F (on ENST00000315939 / NM_018979.4; = p.S1229F on NM_014823.3) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV60028424, COSV60033438; called by muse, mutect2, varscan2
- XDH | c.3646C>T p.P1216S | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs767242541, COSV65148668; called by muse, mutect2, varscan2
- XKR3 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.336); catalogued as COSV58886191; called by muse, mutect2, varscan2
- XKR9 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.265); catalogued as COSV68772942, COSV68772948; called by muse, mutect2, varscan2
- YEATS2 | c.2603C>T p.S868L | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as COSV59365543; called by muse, mutect2, varscan2
- ZBED9 | c.3148C>T p.H1050Y | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as COSV71729411; called by muse, mutect2, varscan2
- ZBTB41 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 107/138 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV66358778, COSV66359174; called by muse, mutect2, varscan2
- ZCCHC2 | c.3326C>T p.P1109L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs768201436, COSV54037781; called by muse, mutect2, varscan2
- ZDHHC19 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV56348756; called by muse, mutect2, varscan2
- ZMAT1 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs768283759, COSV65658591; called by muse, mutect2, varscan2
- ZNF148 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs137930153, COSV62302657; called by muse, mutect2, varscan2
- ZNF281 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 70/82 reads (85%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV54167136; called by muse, mutect2, varscan2
- ZNF30 | c.1044A>T p.E348D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV57853937; called by mutect2, varscan2
- ZNF320 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV67088142; called by muse, mutect2, varscan2
- ZNF527 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.276); catalogued as COSV62230007; called by muse, mutect2, varscan2
- ZNF711 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV52151784; called by muse, mutect2, varscan2
- ZNF711 | c.1670G>A p.G557D | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV52154523; called by muse, mutect2, varscan2
- ZNF80 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100352060; called by muse, mutect2, varscan2
- ZNF80 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100352063; called by muse, varscan2
- ZNF80 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57360792; called by muse, mutect2, varscan2
- ZNF829 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV66986359; called by muse, mutect2, varscan2
- ZPLD1 | c.958G>A p.D320N (on ENST00000466937 / NM_001329788.1; = p.D336N on NM_175056.2) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs756140070, COSV60353601; called by muse, mutect2, varscan2
- ACACA | c.4987C>T p.P1663S | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ACACA | c.3950T>C p.V1317A | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP7B1 | c.1368del p.M457Wfs*3 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- IGHG3 | c.766A>T p.K256* | Nonsense Mutation (SNP) | VAF 203/302 reads (67%) | called by muse, mutect2, varscan2
- IGHV1-45 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 72/115 reads (63%) | SIFT tolerated (0.49); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- IGLV3-12 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- METTL8 | c.454_483del p.E152_G161del | In Frame Del (DEL) | VAF 23/83 reads (28%) | called by mutect2, pindel, varscan2
- MUC2 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.05); called by muse, mutect2
- PKD1L1 | c.8506del p.S2836Lfs*30 | Frame Shift Del (DEL) | VAF 67/209 reads (32%) | called by pindel, varscan2
- POLR2A | c.5831C>T p.S1944F | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2
- TPGS1 | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- A2M | c.657C>T p.F219= | Silent (SNP) | VAF 66/147 reads (45%) | catalogued as COSV59386709; called by muse, mutect2, varscan2
- ABCA12 | c.3378C>T p.I1126= (on ENST00000272895 / NM_173076.3; = p.I808= on NM_015657.3) | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs752505079, COSV55959702; called by muse, mutect2, varscan2
- ABCA13 | c.14007C>T p.L4669= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV68946229; called by muse, mutect2, varscan2
- ABCA6 | c.705A>G p.V235= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1210507610, COSV52638802; called by muse, mutect2, varscan2
- AC020765.6 | c.81C>T p.L27= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs368142835; called by muse, mutect2, varscan2
- ACAN | c.1818C>T p.A606= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV61360603; called by muse, mutect2, varscan2
- ADAM28 | c.822G>A p.E274= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV56099330, COSV56100596; called by muse, mutect2, varscan2
- ADAM28 | c.1233G>A p.G411= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs1464767262, COSV56099444; called by muse, mutect2, varscan2
- ADAMTS17 | c.2694C>T p.V898= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs748217171, COSV51480812; called by muse, mutect2, varscan2
- ADAMTS20 | c.336G>A p.P112= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs781157923, COSV67131682; called by muse, varscan2
- ADD1 | c.1857G>A p.E619= | Silent (SNP) | VAF 31/37 reads (84%) | catalogued as COSV53269257; called by muse, mutect2, varscan2
- AFF2 | c.1722G>A p.T574= | Silent (SNP) | VAF 73/136 reads (54%) | catalogued as rs201846826, COSV53984129, COSV53985561; called by muse, mutect2, varscan2
- AMY2A | c.765G>A p.E255= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV70214507; called by mutect2, varscan2
- ANK3 | c.10401C>T p.I3467= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as rs200592890, COSV55058289; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANO7 | c.2370C>T p.F790= (on ENST00000274979; = p.F736= on NM_001370694.2) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs755797694, COSV99238709; called by muse, mutect2, varscan2
- APLP1 | c.1048C>T p.L350= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV55703446; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1638C>T p.I546= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV59475843; called by muse, mutect2, varscan2
- B4GALNT2 | c.492G>A p.V164= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV55926215; called by muse, mutect2, varscan2
- BAZ2A | c.810C>T p.V270= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV51636839; called by muse, mutect2, varscan2
- BIRC6 | c.1935C>T p.I645= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV70199377; called by muse, mutect2, varscan2
- BRCA1 | c.3372C>T p.F1124= | Silent (SNP) | VAF 47/85 reads (55%) | catalogued as rs786203431, COSV100524930, COSV58790023; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRINP2 | c.1167C>T p.I389= | Silent (SNP) | VAF 89/107 reads (83%) | catalogued as rs1017297077, COSV64177580, COSV64178388; called by muse, mutect2, varscan2
- BTK | c.294C>T p.F98= | Silent (SNP) | VAF 44/74 reads (59%) | catalogued as COSV58120128; called by muse, mutect2, varscan2
- C20orf96 | c.438C>T p.A146= (on ENST00000360321 / NM_153269.3; = p.A145= on NM_080571.1) | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100826845, COSV64403542; called by muse, mutect2, varscan2
- CAP2 | c.246C>T p.F82= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV57732307; called by muse, mutect2, varscan2
- CAVIN2 | c.219G>A p.Q73= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV58424176; called by muse, mutect2, varscan2
- CD207 | c.615C>T p.N205= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV101338571; called by muse, varscan2
- CD93 | c.1758C>T p.I586= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as COSV55665255; called by muse, mutect2, varscan2
- CDH11 | c.105C>T p.F35= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as COSV99218871; called by muse, mutect2, varscan2
- CGNL1 | c.15C>T p.F5= | Silent (SNP) | VAF 182/394 reads (46%) | catalogued as rs765549295, COSV55565288; called by muse, mutect2, varscan2
- CHD8 | c.1842C>T p.L614= (on ENST00000646647 / NM_001170629.2; = p.L335= on NM_020920.4) | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs376100482, COSV67869764; called by muse, mutect2, varscan2
- CLSTN3 | c.1024C>T p.L342= | Silent (SNP) | VAF 58/125 reads (46%) | catalogued as COSV56936309; called by muse, mutect2, varscan2
- CNTN1 | c.2769C>T p.I923= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs754993870, COSV61639718; called by muse, mutect2, varscan2
- CNTN6 | c.1122G>A p.T374= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs1367173526, COSV63172481; called by muse, mutect2, varscan2
- COL3A1 | c.4047C>T p.V1349= | Silent (SNP) | VAF 35/167 reads (21%) | catalogued as COSV100483240; called by muse, mutect2, varscan2
- CPTP | c.177C>T p.S59= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as COSV59563431; called by muse, mutect2, varscan2
- CSF3R | c.2457C>T p.F819= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV58966823; called by muse, mutect2, varscan2
- CWC27 | c.258A>G p.E86= | Silent (SNP) | VAF 119/167 reads (71%) | catalogued as COSV66885876, COSV66887381; called by muse, mutect2, varscan2
- DAGLA | c.1146C>T p.F382= | Silent (SNP) | VAF 25/31 reads (81%) | catalogued as COSV57196127; called by muse, varscan2
- DAZAP2 | c.180C>T p.T60= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV66313010; called by muse, mutect2, varscan2
- DLGAP1 | c.1956C>T p.I652= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs368972216; called by muse, mutect2, varscan2
- DMRTA1 | c.1045C>T p.L349= | Silent (SNP) | VAF 38/55 reads (69%) | catalogued as COSV57924356; called by muse, mutect2, varscan2
- DNAH1 | c.6330C>T p.S2110= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV70229090; called by muse, mutect2, varscan2
- DNAH10 | c.5322G>A p.R1774= (on ENST00000409039; = p.R1713= on NM_207437.3) | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1235194119, COSV68987983; called by muse, mutect2, varscan2
- DNAH11 | c.3783C>T p.F1261= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs1554319441, COSV60956000; called by muse, mutect2, varscan2
- DNAH17 | c.4377G>A p.L1459= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV67754517; called by muse, mutect2, varscan2
- DNAH17 | c.2196G>A p.K732= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV67754524; called by muse, mutect2, varscan2
- DNAH5 | c.9678G>A p.A3226= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as rs547729937, COSV54207337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.5058G>A p.R1686= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as rs267599142, COSV56761477; called by muse, mutect2, varscan2
- DNMBP | c.4122C>T p.F1374= | Silent (SNP) | VAF 34/52 reads (65%) | catalogued as COSV60625261; called by muse, mutect2, varscan2
- DRD5 | c.939C>T p.F313= | Silent (SNP) | VAF 38/59 reads (64%) | catalogued as COSV58578011; called by muse, mutect2, varscan2
- DYNAP | c.369G>A p.V123= (on ENST00000321600; = p.V97= on NM_173629.3) | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV58666376; called by muse, mutect2, varscan2
- EDN3 | c.315G>A p.K105= | Silent (SNP) | VAF 83/156 reads (53%) | catalogued as COSV61108032; called by muse, mutect2, varscan2
- ELAPOR2 | c.2610G>A p.E870= (on ENST00000450689 / NM_001142749.3; = p.E703= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV51887003; called by muse, mutect2, varscan2
- ELN | c.2226C>T p.F742= (on ENST00000320399 / NM_001278939.1; = p.F709= on NM_000501.4) | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV52710333; called by muse, mutect2, varscan2
- EMILIN3 | c.2130G>A p.L710= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV60036271; called by mutect2, varscan2
- ENTPD8 | c.195G>A p.K65= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100395743, COSV58161530; called by muse, mutect2, varscan2
- FAM166A | c.597C>T p.F199= | Silent (SNP) | VAF 36/51 reads (71%) | catalogued as COSV61116717; called by muse, mutect2, varscan2
- FAM47B | c.375G>A p.L125= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs932082927, COSV100264406; called by muse, mutect2, varscan2
- FIBCD1 | c.933G>A p.G311= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs750656149, COSV53393524; called by muse, mutect2, varscan2
- FOXI1 | c.642G>A p.R214= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as COSV60388645; called by muse, mutect2, varscan2
- FSD1 | c.621C>T p.F207= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as rs767652433, COSV55696174; called by mutect2, varscan2
- FYB2 | c.171C>T p.S57= | Silent (SNP) | VAF 77/111 reads (69%) | catalogued as rs769538030, COSV100599577, COSV58584810; called by muse, mutect2, varscan2
- GAB3 | c.1410C>T p.T470= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV65819595; called by muse, mutect2, varscan2
- GABRQ | c.765G>A p.L255= | Silent (SNP) | VAF 21/212 reads (10%) | catalogued as COSV64782085; called by muse, mutect2
- GALNT13 | c.540T>A p.I180= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV67221373; called by muse, mutect2
- GHR | c.1908C>T p.I636= | Silent (SNP) | VAF 56/77 reads (73%) | catalogued as rs866781710, COSV50112895; called by muse, mutect2, varscan2
- GLG1 | c.888C>T p.L296= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as COSV52667140; called by muse, mutect2, varscan2
- GPR139 | c.438G>A p.R146= | Silent (SNP) | VAF 115/170 reads (68%) | catalogued as COSV100429918; called by muse, mutect2, varscan2
- GPR174 | c.531C>T p.V177= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV52132570, COSV52134722; called by muse, mutect2, varscan2
- GPRC6A | c.1503C>T p.F501= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV59953093; called by muse, mutect2, varscan2
- GRIK5 | c.2427C>T p.I809= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs782389187, COSV53474825; called by muse, mutect2, varscan2
- GZMH | c.267C>T p.I89= | Silent (SNP) | VAF 75/106 reads (71%) | catalogued as COSV53538278; called by muse, mutect2, varscan2
- HELZ2 | c.6846C>T p.T2282= (on ENST00000467148 / NM_001037335.2; = p.T1713= on NM_033405.3) | Silent (SNP) | VAF 49/188 reads (26%) | catalogued as rs1286214163, COSV64442785; called by muse, mutect2, varscan2
- HK3 | c.2277C>T p.I759= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as rs369639684; called by muse, mutect2, varscan2
- HLCS | c.1089C>T p.V363= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100358324; called by muse, mutect2, varscan2
- HMGB4 | c.540G>A p.G180= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs867993003, COSV53886137, COSV99592732; called by muse, mutect2, varscan2
- HMGXB4 | c.480C>T p.P160= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs947078168, COSV53334025; called by muse, mutect2, varscan2
- HTR1B | c.429C>T p.I143= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV64051472; called by muse, mutect2, varscan2
- ICAM2 | c.423C>T p.P141= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as COSV56743542; called by muse, mutect2, varscan2
- IER5L | c.684C>T p.A228= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV65262554; called by muse, mutect2, varscan2
- IFNA14 | c.513C>T p.I171= | Silent (SNP) | VAF 189/331 reads (57%) | catalogued as rs372909491; called by muse, mutect2, varscan2
- IGF2R | c.3957C>T p.C1319= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as COSV63629234; called by muse, mutect2, varscan2
- IGHA1 | c.183G>A p.G61= | Silent (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- IL10RA | c.882C>T p.H294= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as COSV57140622; called by muse, mutect2, varscan2
- IL1A | c.36G>A p.K12= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV54519593; called by muse, mutect2, varscan2
- ING1 | c.702C>T p.I234= | Silent (SNP) | VAF 45/83 reads (54%) | catalogued as COSV58169104; called by muse, mutect2, varscan2
- INO80D | c.1023C>T p.P341= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV68958963; called by muse, mutect2, varscan2
- INSRR | c.1326C>T p.F442= | Silent (SNP) | VAF 132/169 reads (78%) | catalogued as COSV63872848; called by muse, mutect2, varscan2
- ITFG1 | c.1233C>T p.D411= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs776956089, COSV57746374, COSV57748973; called by muse, mutect2, varscan2
- ITGB8 | c.375C>T p.I125= | Silent (SNP) | VAF 55/85 reads (65%) | catalogued as COSV56008647; called by muse, mutect2, varscan2
- JARID2 | c.1197C>T p.S399= | Silent (SNP) | VAF 68/169 reads (40%) | catalogued as COSV59189386; called by muse, mutect2, varscan2
- KCNH1 | c.2211C>T p.V737= (on ENST00000271751 / NM_172362.3; = p.V710= on NM_002238.4) | Silent (SNP) | VAF 29/38 reads (76%) | catalogued as COSV55082029; called by muse, mutect2, varscan2
- KCNH4 | c.2394C>T p.P798= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs758032016, COSV52917637; called by muse, mutect2, varscan2
- KCNH5 | c.441G>A p.T147= | Silent (SNP) | VAF 30/41 reads (73%) | catalogued as rs753750382, COSV59752889; called by muse, mutect2, varscan2
- KCNK1 | c.819G>A p.L273= | Silent (SNP) | VAF 40/51 reads (78%) | catalogued as rs1433931586, COSV64034835; called by muse, mutect2, varscan2
- KCNK15 | c.144C>T p.L48= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as rs1404133957, COSV100865830; called by muse, mutect2
- KIF17 | c.2871G>A p.R957= | Silent (SNP) | VAF 79/104 reads (76%) | catalogued as COSV56118202; called by muse, mutect2, varscan2
- KIR2DL4 | c.213C>T p.F71= (on ENST00000396284; = p.F32= on NM_001080770.2) | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as COSV60878339; called by muse, mutect2, varscan2
- KIR3DL3 | c.867G>A p.G289= | Silent (SNP) | VAF 70/128 reads (55%) | called by muse, mutect2, varscan2
- KLHL15 | c.972C>T p.I324= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs144704626, COSV60140310; called by muse, mutect2, varscan2
- KPRP | c.429T>C p.T143= | Silent (SNP) | VAF 117/149 reads (79%) | catalogued as rs1190636598, COSV64220881, COSV64221403; called by muse, mutect2, varscan2
- KRT6C | c.48G>A p.R16= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1209287312, COSV52877829; called by muse, mutect2, varscan2
- KSR1 | c.2199G>A p.G733= (on ENST00000644974 / NM_001367810.1; = p.G618= on NM_014238.2) | Silent (SNP) | VAF 110/227 reads (48%) | catalogued as COSV52032829; called by muse, mutect2, varscan2
- KSR2 | c.2175C>T p.F725= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs887069309, COSV56672676; called by muse, mutect2, varscan2
- LAMB1 | c.2091C>T p.P697= | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as COSV55964700; called by muse, mutect2, varscan2
- LGSN | c.1023G>A p.G341= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV65726548; called by muse, mutect2, varscan2
- LPCAT4 | c.570C>T p.T190= | Silent (SNP) | VAF 109/243 reads (45%) | catalogued as COSV59216842; called by muse, mutect2, varscan2
- LRP1B | c.4386C>T p.I1462= | Silent (SNP) | VAF 43/76 reads (57%) | catalogued as COSV67221314; called by muse, mutect2, varscan2
- LRRC1 | c.1047G>A p.R349= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV63829140; called by muse, mutect2, varscan2
- MAGEC3 | c.720C>T p.S240= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as COSV53580435; called by muse, mutect2, varscan2
- MFSD2A | c.1026C>T p.F342= (on ENST00000372809 / NM_001136493.3; = p.F329= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 48/69 reads (70%) | catalogued as COSV65685633; called by muse, mutect2, varscan2
- MGA | c.4731C>T p.V1577= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs778703493, COSV54953284; called by muse, mutect2, varscan2
- MICAL3 | c.4494C>T p.P1498= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV71588327; called by muse, mutect2, varscan2
- MINDY1 | c.859C>T p.L287= | Silent (SNP) | VAF 179/220 reads (81%) | catalogued as rs772740181, COSV56498861; called by muse, mutect2, varscan2
- MPO | c.1347C>T p.I449= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs746831572, COSV56561153, COSV99832387; called by muse, mutect2, varscan2
- MRPS23 | c.66C>T p.A22= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs755842412, COSV100551451; called by muse, mutect2, varscan2
- MUC16 | c.23043G>A p.V7681= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV67446907; called by muse, mutect2, varscan2
- MUC16 | c.9021C>T p.T3007= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs1285421417, COSV67466639; called by muse, mutect2, varscan2
- MUC16 | c.7323C>T p.S2441= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV67466643; called by muse, mutect2, varscan2
- MUC16 | c.2265G>A p.G755= | Silent (SNP) | VAF 58/104 reads (56%) | catalogued as rs763134274, COSV67466655; called by muse, mutect2, varscan2
- MXRA5 | c.7359G>A p.R2453= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV54235452, COSV54247716; called by muse, mutect2, varscan2
- MYCBP2 | c.7116T>C p.T2372= (on ENST00000357337; = p.T2410= on NM_015057.5) | Silent (SNP) | VAF 10/216 reads (5%) | catalogued as COSV62019629; called by muse, mutect2
- MYH2 | c.2040C>T p.I680= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV55434173; called by muse, mutect2, varscan2
- MYH2 | c.471C>T p.S157= | Silent (SNP) | VAF 52/313 reads (17%) | catalogued as rs149579742, COSV55433178; called by muse, mutect2, varscan2
- MYOM2 | c.1704G>A p.P568= | Silent (SNP) | VAF 39/59 reads (66%) | catalogued as rs763212505, COSV50713433, COSV50728656; called by muse, mutect2, varscan2
- NEURL4 | c.2295C>T p.V765= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs769491670, COSV59749706; called by muse, mutect2, varscan2
- NLRP4 | c.2118C>T p.L706= | Silent (SNP) | VAF 34/55 reads (62%) | catalogued as COSV56713803, COSV56723693; called by muse, mutect2, varscan2
- NLRP5 | c.120C>T p.F40= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs369527947; called by mutect2, varscan2
- NOS1 | c.96G>A p.V32= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV57612135; called by muse, mutect2, varscan2
- NYNRIN | c.4269C>T p.S1423= | Silent (SNP) | VAF 41/64 reads (64%) | catalogued as rs267603972, COSV66842269; called by muse, varscan2
- OPLAH | c.1218C>T p.F406= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV70677970; called by muse, varscan2
- OR10G4 | c.660C>T p.I220= | Silent (SNP) | VAF 53/70 reads (76%) | catalogued as rs1338777128, COSV100305045, COSV57977173; called by muse, mutect2, varscan2
- OR10T2 | c.315C>T p.F105= | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as COSV57781403; called by muse, mutect2, varscan2
- OR11L1 | c.660C>T p.F220= | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as COSV63313450, COSV63314124; called by muse, mutect2, varscan2
- OR14J1 | c.798G>A p.S266= | Silent (SNP) | VAF 70/149 reads (47%) | catalogued as rs531580647, COSV65845618; called by muse, mutect2, varscan2
- OR1J1 | c.471T>G p.L157= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV52238489; called by muse, mutect2, varscan2
- OR2F2 | c.672C>T p.T224= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs199769704, COSV101283858, COSV68832793; called by muse, mutect2, varscan2
- OR2T2 | c.501C>T p.F167= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs1385992159, COSV100737574; called by muse, mutect2, varscan2
- OR3A1 | c.726C>T p.S242= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1190315717, COSV60163113; called by muse, mutect2, varscan2
- OR4K13 | c.834C>T p.F278= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as COSV59859640; called by muse, mutect2, varscan2
- OR51D1 | c.849C>T p.L283= | Silent (SNP) | VAF 73/116 reads (63%) | catalogued as COSV62914205; called by muse, mutect2, varscan2
- OR51T1 | c.357C>T p.A119= | Silent (SNP) | VAF 51/72 reads (71%) | catalogued as COSV59025497; called by muse, mutect2, varscan2
- OR6C4 | c.159C>T p.L53= | Silent (SNP) | VAF 67/312 reads (21%) | catalogued as COSV67792851, COSV67793333; called by muse, mutect2, varscan2
- PAOX | c.852C>T p.I284= | Silent (SNP) | VAF 36/54 reads (67%) | catalogued as rs772609287, COSV53372453; called by muse, mutect2, varscan2
- PCDH10 | c.774C>T p.S258= | Silent (SNP) | VAF 51/84 reads (61%) | catalogued as COSV52094210, COSV99994179; called by muse, mutect2, varscan2
- PCDHGA2 | c.537C>T p.S179= | Silent (SNP) | VAF 66/93 reads (71%) | catalogued as rs958951801, COSV53949631; called by muse, mutect2, varscan2
- PCED1B | c.168C>T p.F56= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV71395017; called by muse, mutect2, varscan2
- PDE3A | c.1818G>A p.G606= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs757295809, COSV62973052; called by muse, mutect2, varscan2
- PDLIM5 | c.1629T>C p.F543= | Silent (SNP) | VAF 53/82 reads (65%) | catalogued as COSV58747810; called by muse, mutect2, varscan2
- PEX6 | c.855C>T p.P285= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV55103027, COSV55103166; called by muse, mutect2, varscan2
- PHKG1 | c.774G>A p.S258= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs145703798; called by muse, mutect2, varscan2
- PKD1L1 | c.5808C>T p.F1936= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV56965204; called by muse, mutect2, varscan2
- PKHD1L1 | c.4194G>A p.G1398= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV65743076; called by muse, mutect2, varscan2
- PLCD3 | c.870C>T p.A290= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100504287; called by muse, mutect2, varscan2
- PLEKHG2 | c.2677C>T p.L893= | Silent (SNP) | VAF 35/54 reads (65%) | catalogued as COSV52683392, COSV52689753; called by muse, mutect2, varscan2
- POLR2A | c.5829T>C p.T1943= | Silent (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2
- POU5F2 | c.405G>A p.Q135= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as COSV67937555; called by muse, mutect2, varscan2
- PRAMEF12 | c.1002C>T p.F334= | Silent (SNP) | VAF 53/61 reads (87%) | catalogued as COSV63215337; called by muse, mutect2, varscan2
- PREX1 | c.4359C>T p.S1453= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100906502; called by muse, mutect2, varscan2
- PRKN | c.1230C>T p.T410= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV58226911; called by muse, mutect2, varscan2
- PRR12 | c.2484C>T p.F828= (on ENST00000615927; = p.F1649= on NM_020719.3) | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV69816561; called by muse, mutect2, varscan2
- PTPRK | c.951C>T p.I317= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV63887677; called by muse, mutect2, varscan2
- PTPRT | c.847C>T p.L283= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as rs1303503165, COSV61981843; called by muse, mutect2, varscan2
- PTX4 | c.870C>T p.F290= (on ENST00000447419 / NM_001328608.2; = p.F285= on NM_001013658.1) | Silent (SNP) | VAF 23/32 reads (72%) | catalogued as rs547860335, COSV53516488; called by muse, mutect2, varscan2
- RAI1 | c.4701C>T p.P1567= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV55393136; called by muse, mutect2, varscan2
- RNF207 | c.1614C>T p.V538= | Silent (SNP) | VAF 32/42 reads (76%) | catalogued as rs755341845, COSV65007673; called by muse, mutect2, varscan2
- RSAD1 | c.318C>T p.P106= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV51955687; called by muse, mutect2, varscan2
- RTL4 | c.222C>T p.F74= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs267606321, COSV61206260; called by muse, mutect2, varscan2
- RXFP2 | c.2097G>A p.K699= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV53635814; called by muse, mutect2, varscan2
- RXYLT1 | c.300A>T p.V100= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV54168453; called by muse, mutect2, varscan2
- RYR2 | c.10290C>T p.F3430= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV63686211; called by muse, mutect2, varscan2
- SAFB | c.2580C>A p.S860= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV52651430; called by muse, mutect2, varscan2
- SCN3A | c.3078C>T p.F1026= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as COSV51810150; called by muse, mutect2, varscan2
- SCN5A | c.1284G>A p.E428= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV61124299; called by muse, mutect2, varscan2
- SCN7A | c.1812C>T p.F604= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV69271612; called by muse, mutect2, varscan2
- SDR16C5 | c.786A>G p.K262= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV58126527; called by muse, varscan2
- SEC23B | c.1164C>T p.F388= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as COSV52720328; called by muse, mutect2, varscan2
- SERPINB4 | c.12C>T p.L4= | Silent (SNP) | VAF 72/196 reads (37%) | catalogued as COSV61984964; called by muse, varscan2
- SHBG | c.705C>T p.F235= | Silent (SNP) | VAF 123/237 reads (52%) | catalogued as COSV52646818; called by muse, mutect2, varscan2
- SHPRH | c.2307C>T p.I769= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV51609415; called by muse, mutect2, varscan2
- SI | c.3201C>T p.I1067= | Silent (SNP) | VAF 70/178 reads (39%) | catalogued as COSV100016952, COSV52279054; called by muse, mutect2, varscan2
- SIRPB1 | c.708G>A p.G236= | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as rs1177322601, COSV53538799; called by muse, mutect2, varscan2
- SLC10A2 | c.399C>T p.S133= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV55358963, COSV55361464; called by muse, mutect2, varscan2
- SLC25A47 | c.390G>A p.Q130= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV64161871; called by muse, mutect2, varscan2
- SLC27A6 | c.465C>T p.A155= | Silent (SNP) | VAF 17/22 reads (77%) | catalogued as rs538309779, COSV52483118; called by muse, mutect2, varscan2
- SLC41A3 | c.447C>T p.L149= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1438537805, COSV59988248; called by muse, mutect2, varscan2
- SLC6A5 | c.1032G>A p.S344= | Silent (SNP) | VAF 63/101 reads (62%) | catalogued as rs758648041, COSV54226720, COSV54229582; called by muse, mutect2, varscan2
- SLC9A6 | c.861G>A p.A287= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs185192141, COSV65788016; ClinVar: benign; called by muse, mutect2, varscan2
- SLC9C1 | c.1779G>A p.E593= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs139599943; called by muse, mutect2, varscan2
- SLFN13 | c.807G>A p.L269= | Silent (SNP) | VAF 72/133 reads (54%) | catalogued as COSV53193583; called by muse, mutect2, varscan2
- SLITRK6 | c.1843C>T p.L615= | Silent (SNP) | VAF 49/77 reads (64%) | catalogued as COSV68390235; called by muse, mutect2, varscan2
- SMARCA2 | c.2691C>T p.F897= | Silent (SNP) | VAF 30/50 reads (60%) | catalogued as COSV61807548; called by muse, mutect2, varscan2
- SMOC2 | c.309G>A p.K103= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV62438105; called by muse, mutect2, varscan2
- SPACA3 | c.603C>T p.C201= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs1471557549, COSV52190411; called by muse, mutect2, varscan2
- SPATA31E1 | c.2025C>T p.L675= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV57791471; called by muse, mutect2, varscan2
- SPATA5 | c.2586C>T p.F862= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as COSV56776146; called by muse, mutect2, varscan2
- SPINT1 | c.1053C>T p.F351= (on ENST00000344051 / NM_181642.3; = p.F335= on NM_003710.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV59801919; called by muse, mutect2, varscan2
- SRCAP | c.7629C>T p.L2543= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV52672739; called by muse, mutect2
- STAT5B | c.538C>T p.L180= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV53182595; called by muse, mutect2, varscan2
- STOX2 | c.414C>T p.I138= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs960476986, COSV57848764; called by muse, mutect2, varscan2
- SUGP2 | c.2064C>T p.L688= | Silent (SNP) | VAF 46/78 reads (59%) | catalogued as COSV58258915; called by muse, varscan2
- SUGP2 | c.2046C>T p.L682= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs139001412; called by muse, varscan2
- SYNE3 | c.420C>T p.I140= | Silent (SNP) | VAF 41/62 reads (66%) | catalogued as rs532215612, COSV62079489; called by muse, mutect2, varscan2
- TADA2B | c.696C>T p.F232= | Silent (SNP) | VAF 44/64 reads (69%) | catalogued as COSV53827298; called by muse, mutect2, varscan2
- TAMM41 | c.258C>T p.S86= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV56071803; called by muse, mutect2, varscan2
- THSD4 | c.66C>T p.F22= | Silent (SNP) | VAF 66/136 reads (49%) | catalogued as rs1425585373, COSV55968032; called by muse, mutect2, varscan2
- TLR7 | c.1998T>C p.P666= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV66124323; called by muse, mutect2, varscan2
- TMEM132D | c.645C>T p.S215= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs1392044872, COSV70596653; called by muse, mutect2, varscan2
- TMEM225 | c.627G>A p.V209= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as COSV66693207; called by muse, mutect2, varscan2
- TMEM38A | c.438C>T p.F146= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as rs768099700, COSV51819100; called by muse, mutect2, varscan2
- TNXB | c.4020G>A p.V1340= (on ENST00000647633; = p.V1093= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV64479096; called by muse, mutect2, varscan2
- TOX2 | c.732G>A p.P244= (on ENST00000358131 / NM_001098798.2; = p.P193= on NM_032883.3) | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs766856606, COSV57884090; called by muse, mutect2, varscan2
- TREML2 | c.126C>T p.S42= | Silent (SNP) | VAF 65/163 reads (40%) | catalogued as rs1453416800, COSV72439119; called by muse, mutect2, varscan2
- TRIM26 | c.699C>T p.A233= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs1461187524, COSV68963091; called by muse, mutect2, varscan2
- TRPM6 | c.5916C>T p.C1972= | Silent (SNP) | VAF 56/68 reads (82%) | catalogued as COSV62510441; called by muse, mutect2, varscan2
- TRPM7 | c.2691C>T p.A897= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV57916496; called by muse, mutect2, varscan2
- TRRAP | c.7849C>T p.L2617= (on ENST00000359863 / NM_001244580.1; = p.L2599= on NM_003496.3) | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV62844416; called by muse, mutect2, varscan2
- TSGA13 | c.234G>A p.R78= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV63018681; called by muse, mutect2, varscan2
- TTC13 | c.2379C>T p.P793= | Silent (SNP) | VAF 166/201 reads (83%) | catalogued as COSV64168615; called by muse, mutect2, varscan2
- TUBA3C | c.342C>T p.I114= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs983622040, COSV67138914; called by mutect2, varscan2
- TUBE1 | c.1158C>T p.S386= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs267600764, COSV57889373; called by muse, mutect2, varscan2
- UBAP2L | c.2373C>T p.L791= | Silent (SNP) | VAF 38/57 reads (67%) | catalogued as COSV55172631, COSV55173182; called by muse, mutect2, varscan2
- ULK4 | c.603C>T p.D201= | Silent (SNP) | VAF 72/220 reads (33%) | catalogued as COSV57209110, COSV57216891; called by muse, mutect2, varscan2
- USP6 | c.2664C>T p.F888= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as rs746998044, COSV51482594; called by muse, mutect2, varscan2
- WWTR1 | c.555C>T p.S185= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs753382684, COSV62291360; called by muse, mutect2, varscan2
- ZFAT | c.1401C>T p.F467= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs199619199; called by muse, mutect2, varscan2
- ZFHX4 | c.7740G>A p.R2580= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV50809643; called by muse, mutect2, varscan2
- ZFP90 | c.942C>T p.L314= | Silent (SNP) | VAF 31/45 reads (69%) | catalogued as COSV68050956; called by muse, mutect2, varscan2
- ZNF560 | c.684C>T p.C228= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs764164321, COSV56867928; called by muse, mutect2, varscan2
- ZNF598 | c.1941C>T p.P647= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as rs747025172, COSV70910640; called by muse, mutect2, varscan2
- ZNF714 | c.561C>T p.T187= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV52511984; called by muse, mutect2, varscan2
- ATG13 | c.790-792C>T | Intron (SNP) | VAF 57/198 reads (29%) | catalogued as COSV56319464; called by muse, mutect2, varscan2
- DLX1 | c.*2G>A | 3'UTR (SNP) | VAF 67/151 reads (44%) | catalogued as COSV100543258; called by muse, mutect2, varscan2
- FAM183BP | n.939G>A | RNA (SNP) | VAF 23/35 reads (66%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1399G>A | RNA (SNP) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- LEKR1 | c.*1431G>A | 3'UTR (SNP) | VAF 85/169 reads (50%) | catalogued as COSV62962075; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+740G>A | Intron (SNP) | VAF 50/159 reads (31%) | catalogued as COSV99196191; called by muse, mutect2, varscan2
- PSG5 | c.431-2929C>T | Intron (SNP) | VAF 31/167 reads (19%) | catalogued as COSV100742888; called by muse, mutect2, varscan2
- SNORD114-6 | n.34C>T | RNA (SNP) | VAF 10/38 reads (26%) | catalogued as rs780077095; called by muse, mutect2, varscan2
- SNORD115-44 | n.67G>A | RNA (SNP) | VAF 88/344 reads (26%) | called by muse, mutect2, varscan2
- SUGP1 | c.539-85T>A | Intron (SNP) | VAF 16/114 reads (14%) | catalogued as COSV99895205; called by muse, varscan2
- SUGP1 | c.539-163C>T | Intron (SNP) | VAF 110/190 reads (58%) | catalogued as COSV99895206; called by muse, varscan2
- XIRP2 | c.-18G>A | 5'UTR (SNP) | VAF 22/89 reads (25%) | catalogued as COSV54701081; called by muse, mutect2, varscan2
